Somatic mutation profile of tumor specimen TCGA-ZG-A9L1-01A (aliquot TCGA-ZG-A9L1-01A-11D-A41K-08) from TCGA case TCGA-ZG-A9L1, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.3 years (24,214 days).
Specimen TCGA-ZG-A9L1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c1a1571-9505-4157-8b1e-c2361743dafa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9L1-10A (Blood Derived Normal), aliquot TCGA-ZG-A9L1-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0170b7e9-fc21-4735-bcc8-54e6693da3ab

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Frame Shift Del 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 22/36 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- BTBD3 | c.1391A>G p.D464G | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.261); catalogued as COSV99655835; called by muse, mutect2, varscan2
- CCHCR1 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV100885632; called by muse, mutect2, varscan2
- CNTNAP1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99226310; called by muse, mutect2
- DOK6 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101234478; called by muse, mutect2, varscan2
- IGKV1-8 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs747029658; called by muse, mutect2, varscan2
- KIF13A | c.5362G>C p.E1788Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.018); catalogued as COSV99435792; called by muse, mutect2, varscan2
- MARCHF7 | c.388A>G p.M130V | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375119177; called by muse, mutect2, varscan2
- MED13 | c.5476A>T p.N1826Y | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101181017; called by muse, mutect2, varscan2
- OR4C12 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58859951; called by muse, mutect2, varscan2
- PERP | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.025); catalogued as COSV101408587; called by muse, mutect2, varscan2
- PYHIN1 | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV100932334, COSV100932348; called by muse, varscan2
- SIGLEC15 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV101248846; called by muse, mutect2, varscan2
- SQOR | c.965C>A p.T322N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV99525756; called by muse, mutect2, varscan2
- SVEP1 | c.3398C>A p.P1133H | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275435654, COSV100237937; called by muse, mutect2
- SYNE1 | c.4946C>T p.A1649V (on ENST00000367255 / NM_182961.4; = p.A1656V on NM_033071.3) | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs781768971, COSV55014482; called by muse, mutect2, varscan2
- UBN1 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1336535830, COSV99277930; called by muse, mutect2, varscan2
- DRD3 | c.444dup p.R149Afs*25 | Frame Shift Ins (INS) | VAF 20/63 reads (32%) | called by mutect2, pindel, varscan2
- LMTK2 | c.1585_1586del p.V529Pfs*12 | Frame Shift Del (DEL) | VAF 23/62 reads (37%) | called by mutect2, pindel, varscan2
- MMP20 | c.254_255del p.G85Efs*19 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- AP2A2 | c.1884G>A p.E628= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV100172836; called by muse, mutect2, varscan2
- BAZ2B | c.5685G>T p.G1895= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100600603; called by muse, mutect2
- GORASP1 | c.642T>C p.P214= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1401308993, COSV100073091; called by muse, mutect2, varscan2
- KCNH5 | c.729C>T p.N243= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100526413; called by muse, mutect2, varscan2
- MYO1E | c.1821C>T p.V607= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as rs375000696; called by muse, mutect2, varscan2
- PAX6 | c.822G>A p.Q274= | Silent (SNP) | VAF 50/97 reads (52%) | catalogued as COSV99570398; called by muse, mutect2, varscan2
- PTPRH | c.2466C>T p.D822= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs149252651; called by muse, mutect2, varscan2
